Somatic mutation profile of tumor specimen ALCH-AD8I-TTP1-A (aliquot ALCH-AD8I-TTP1-A-2-0-D-A532-36) from ALCHEMIST case ALCH-AD8I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,933 days).
Specimen ALCH-AD8I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aef5366-5dbd-45c8-b26d-4ac602182b49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD8I-NB1-A (Blood Derived Normal), aliquot ALCH-AD8I-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2c1953d-a58a-46fa-9a5c-62a36876d097

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 41/442 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- SF3B1 | c.2221A>C p.K741Q | Missense Mutation (SNP) | VAF 12/340 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1380834335, COSV59207072, COSV59211907, COSV59219639; called by muse, mutect2
- C10orf90 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs370672577; called by muse, mutect2
- GNAZ | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV50737743; called by muse, mutect2, varscan2
- GPR42 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV101497374; called by muse, mutect2
- MAGEB5 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.077); catalogued as rs188995747, COSV66869219; called by muse, varscan2
- PCDHA4 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.051); catalogued as rs782620777, COSV63542919; called by muse, mutect2
- TAOK3 | c.533T>G p.F178C | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66827663; called by muse, mutect2
- YAE1 | c.25T>G p.L9V | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs887302310, COSV99784967; called by muse, mutect2
- ADAMTSL5 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2
- AOX1 | c.3536A>G p.D1179G | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); called by muse, mutect2
- CARNS1 | c.2009T>C p.L670P | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.897); called by muse, mutect2
- KNTC1 | c.2065G>C p.V689L | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2
- LDLRAD2 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- PDZD8 | c.996-3C>T | Splice Region (SNP) | VAF 16/382 reads (4%) | called by muse, mutect2
- RSAD2 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.031); called by muse, mutect2
- SLTM | c.3055A>C p.S1019R | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- USP47 | c.974T>G p.L325R (on ENST00000399455 / NM_001372095.1; = p.L237R on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XYLT1 | c.1870A>G p.T624A | Missense Mutation (SNP) | VAF 10/307 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- ZFR | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 26/419 reads (6%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ZSWIM1 | c.500T>G p.L167R | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.234); called by muse, mutect2
- AP4B1 | c.123T>G p.T41= | Silent (SNP) | VAF 14/398 reads (4%) | called by muse, mutect2
- OPN1LW | c.642C>T p.P214= | Silent (SNP) | VAF 15/203 reads (7%) | catalogued as rs138979991, COSV64049614; called by muse, mutect2
- FAS | c.*1157A>G | 3'UTR (SNP) | VAF 10/280 reads (4%) | called by muse, mutect2
